BEATAML1.0 case 2349 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/454cf2c2-71fa-4b3f-b68e-955ed28224c5

Biospecimens (1 sample)
- Sample BA2827R: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
